Somatic mutation profile of tumor specimen TCGA-3C-AALJ-01A (aliquot TCGA-3C-AALJ-01A-31D-A41F-09) from TCGA case TCGA-3C-AALJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.6 years (22,848 days).
Specimen TCGA-3C-AALJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9ec5332-e422-453d-b3e0-5254bb88934d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3C-AALJ-10A (Blood Derived Normal), aliquot TCGA-3C-AALJ-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e007f75b-2389-4b68-95c2-7a84257fd241

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, In Frame Del 2, Frame Shift Del 2, 5'Flank 1, RNA 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANP32E | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs782603651, COSV58481542; called by muse, mutect2, varscan2
- ARFIP2 | c.274A>C p.K92Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99601663; called by muse, mutect2, varscan2
- BMP2K | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58594399; called by muse, mutect2, varscan2
- CACNA1A | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1365721398, COSV64200218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCOCO1 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100017480; called by muse, mutect2, varscan2
- CEMIP | c.2495A>T p.E832V | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV99587253; called by muse, mutect2, varscan2
- DIRAS2 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65370857; called by mutect2, varscan2
- FGFR1 | c.591C>G p.F197L (on ENST00000447712 / NM_023110.3; = p.F195L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/374 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as CM111617, COSV100249164, COSV58330373; called by muse, mutect2, varscan2
- FGFR2 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs779423644, COSV100337183; called by muse, mutect2, varscan2
- GDF11 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV99144080; called by muse, mutect2, varscan2
- GMEB1 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as COSV99603463; called by muse, mutect2, varscan2
- IL1F10 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV61750707; called by muse, mutect2, varscan2
- KANK3 | c.2201T>C p.M734T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100035645; called by muse, mutect2, varscan2
- KMT2D | c.5042C>A p.T1681N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99985611; called by muse, mutect2, varscan2
- LRCH3 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV99611950; called by muse, mutect2, varscan2
- MLLT10 | c.2063G>T p.R688L (on ENST00000307729 / NM_001195626.3; = p.R704L on NM_004641.3) | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56997380, COSV57001896; called by muse, mutect2, varscan2
- SNX6 | c.428+1G>T p.X143_splice (on ENST00000652385; = p.X15_splice on NM_021249.5) | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100751575, COSV61919299; called by muse, mutect2, varscan2
- TBX3 | c.794del p.Y265Lfs*17 (on ENST00000257566 / NM_016569.4; = p.Y245Lfs*17 on NM_005996.4) | Frame Shift Del (DEL) | VAF 71/191 reads (37%) | catalogued as COSV99983682; called by mutect2, pindel*, varscan2*
- TEKT5 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs138237208; called by muse, mutect2, varscan2
- TTN | c.30421G>C p.V10141L (on ENST00000591111; = p.V9214L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/177 reads (38%) | PolyPhen benign (0.021); catalogued as COSV100629025; called by muse, mutect2, varscan2
- ZNF385B | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs753184978, COSV61176049; called by muse, mutect2, varscan2
- GATA3 | c.1266dup p.H423Afs*84 | Frame Shift Ins (INS) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- PLK2 | c.1161_1162del p.R387Sfs*3 | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | called by pindel, varscan2
- TMEM245 | c.2498_2512del p.L833_N838delinsH | In Frame Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, pindel
- TUFT1 | c.171_173del p.H57_S58delinsQ | In Frame Del (DEL) | VAF 18/131 reads (14%) | called by mutect2, pindel, varscan2
- AEBP1 | c.159C>T p.D53= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- DHX16 | c.271C>T p.L91= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100906152; called by muse, mutect2
- EDRF1 | c.1905G>A p.P635= (on ENST00000356792 / NM_001202438.2; = p.P601= on NM_015608.2) | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs199597232, COSV61765032; called by muse, mutect2, varscan2
- PRR19 | c.699G>C p.G233= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100004111; called by muse, mutect2
- YWHAB | c.435G>T p.S145= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as COSV100803205, COSV62303957; called by muse, mutect2, varscan2
- CHCHD2P9 | n.373G>A | RNA (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- YOD1 | chr1:207052219 A>G | 5'Flank (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100263256; called by muse, mutect2, varscan2
